Gene-level copy-number profile of tumor specimen TCGA-L5-A4ON-01A from TCGA case TCGA-L5-A4ON, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIB; Tumor grade: GX; Age at diagnosis: 65.6 years (23,970 days).
Specimen TCGA-L5-A4ON-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.db2302a4-1cb6-4bb0-8bcf-adcb381278b0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-L5-A4ON-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2.
https://portal.gdc.cancer.gov/files/f2a86e51-f929-40c6-9623-e66edc812603

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 2,514; copy number 2: 36,068; copy number 3: 12,848; copy number 4: 7,325; copy number 5: 522; copy number 6: 121; copy number 7: 155; copy number 8: 94; copy number 9: 13; copy number 10: 10; copy number 11: 85; copy number 14: 60.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,730,644, 4 genes (within-gene range 0–2): AC104164.2, MIR548BB, PPIAP70, AC104164.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,060 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:32,481,312–34,677,247, 36 genes, copy number 6–9: CMTM6, MIR548AY, AC104306.1, DYNC1LI1, AC104306.2, IGBP1P3, RPL30P4, CNOT10, CNOT10-AS1, SUGT1P2, RPL23AP43, TRIM71, CCR4, GLB1, SEC13P1, SUMO2P10, TMPPE, RN7SL296P, CRTAP, AC112211.1, SUSD5, AC123900.1, FBXL2, UBP1, RNU7-110P, RNA5SP128, CLASP2, COX6CP10, AC112220.1, SDAD1P3, AC112220.2, PDCD6IP, LINC01811, AC123023.2, AC123023.1, AC018359.1.
- chr4:83,636,196–84,651,334, 9 genes, copy number 7: Y_RNA, AC021192.1, AC079160.1, RNU6-774P, AC025538.1, AC104063.1, NKX6-1, RPL3P13, CDS1.
- chr4:84,687,725–84,688,000, 1 gene, copy number 7: RN7SL552P.
- chr6:40,713,411–44,553,281, 149 genes, copy number 5–14 (broad region; genes not listed).
- chr6:63,193,072–63,779,336, 16 genes, copy number 7: AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3.
- chr6:63,797,189–63,857,769, 3 genes, copy number 7: AL354719.1, SCAT8, GCNT1P4.
- chr6:117,907,264–118,317,676, 1 gene, copy number 5 (within-gene range 2–5): SLC35F1.
- chr6:118,452,469–123,637,093, 58 genes, copy number 5–8 (within-gene range 2–8): AL589993.1, CEP85L, BRD7P3, PLN, Z99496.1, SSXP10, SELENOKP3, MCM9, ASF1A, AL137009.1, FAM184A, Y_RNA, MIR548B, AL022722.2, MAN1A1, AL022722.1, RNU6-194P, AL078600.1, MIR3144, AL096854.1, RNU6-214P, RNA5SP215, COX6A1P3, AL357513.1, TBC1D32, RNU6-1286P, Y_RNA, AL139098.1, AL139098.2, GJA1, RNU4-35P, AL138729.1, RNU4-76P, RNU2-8P, AL603865.2, SLC25A5P7, RPL23AP48, AL603865.1, HMGB3P18, RNU1-18P, HSF2, Z99129.4, SERINC1, Z99129.1, PKIB, Z99129.3, Z99129.2, AL512283.2, AL512283.1, AL512283.3, RN7SL564P, FABP7, SMPDL3A, ATP5MGP2, AL591428.1, CLVS2, TRDN, TRDN-AS1.
- chr6:127,266,682–130,146,179, 39 genes, copy number 7: RNF146, ECHDC1, RNA5SP217, YWHAZP4, RPL5P18, AL590002.1, AL096711.1, KIAA0408, AL096711.2, SOGA3, C6orf58, AL592291.1, AL356432.1, AL356432.3, AL356432.2, LINC02536, THEMIS, MRPS17P5, PTPRK, PTPRK-AS1, AL034349.1, EEF1DP5, Y_RNA, AL080315.1, Y_RNA, LAMA2, MESTP1, BMPR1AP1, RNU6-861P, AL356124.1, AL356124.2, ARHGAP18, RPL5P21, AL451046.2, B3GALNT2P1, AL451046.1, TMEM244, L3MBTL3, AL355581.1.
- chr7:11,180,902–11,520,175, 1 gene, copy number 6 (within-gene range 3–6): AC004160.1.
- chr7:11,370,365–11,832,198, 3 genes, copy number 6: THSD7A, AC004160.2, THRAP3P3.
- chr7:25,134,692–28,243,917, 93 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr8:1,565,509–5,072,869, 38 genes, copy number 5 (within-gene range 4–5): DLGAP2-AS1, AC100810.6, AC100810.2, CLN8, AC100810.3, AC100810.1, AC019257.8, MIR3674, AC100810.7, MIR596, ARHGEF10, AC019257.9, AC019257.1, KBTBD11-OT1, KBTBD11, AC019257.2, AC245164.1, MYOM2, MIR7160, AC245164.2, AC245519.1, AC245519.2, AC245187.2, AC245187.1, AC245123.1, AC246817.2, AC246817.1, AC115485.1, AC023296.1, CSMD1, AC026991.1, AC026991.2, RNA5SP251, AC027251.1, AC010941.1, AC022068.1, PAICSP4, AC019176.1.
- chr9:32,979,560–34,922,921, 95 genes, copy number 5 (broad region; genes not listed).
- chr11:25,588,475–28,683,469, 38 genes, copy number 5: RPL36AP40, AC100770.1, LINC02699, AC013799.1, AC024341.1, ANO3, AC021698.1, ANO3-AS1, AC079064.1, MUC15, SLC5A12, FIBIN, BBOX1, BBOX1-AS1, CCDC34, LGR4, LGR4-AS1, AC100771.1, LIN7C, BDNF-AS, MIR8087, RNA5SP339, AC104563.1, LINC00678, BDNF, AC103796.1, CBX3P1, HSP90AA2P, AC090159.1, KIF18A, MIR610, METTL15, ATP5MGP8, RN7SKP158, AC104978.1, MIR8068, AC013714.1, LINC02758.
- chr11:55,262,155–55,368,918, 10 genes, copy number 10: TRIM48, AP005597.4, AP005597.3, AP005597.2, TRIM51HP, AP005597.1, OR4A11P, OR4A12P, OR4A16, OR4A15.
- chr18:10,297,299–13,919,923, 116 genes, copy number 5 (broad region; genes not listed).
- chr19:18,306,236–20,847,417, 130 genes, copy number 7–8 (broad region; genes not listed).
- chr20:35,302,566–41,712,600, 156 genes, copy number 5–8 (within-gene range 4–8) (broad region; genes not listed).
- chr20:43,796,437–45,080,021, 38 genes, copy number 7: RNU6-639P, LINC01728, TOX2, RN7SL443P, JPH2, AL035447.1, OSER1, OSER1-DT, GDAP1L1, FITM2, R3HDML, Y_RNA, AL117382.1, HNF4A, HNF4A-AS1, AL117382.2, MIR3646, LINC01620, RPL37AP1, TTPAL, SERINC3, PKIG, ADA, LINC01260, AL139352.1, KCNK15-AS1, CCN5, KCNK15, AL118522.1, RIMS4, PGBD4P2, AL008725.1, YWHAB, PABPC1L, TOMM34, STK4-AS1, STK4, Y_RNA.
- chr20:52,671,735–54,859,812, 30 genes, copy number 6: AL031674.1, AL161945.1, AL121902.1, RPL36P1, TSHZ2, RN7SKP184, AL391097.3, AL391097.1, AL391097.2, AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC005914.1, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1, AL133335.2, PFDN4, AL133335.1, DOK5, RNU4ATAC7P.

Autosomal genes at a single copy (total copy number 1): 1,770. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
